CCDI case PBCLWD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/6d466544-5846-4b49-8b9e-b5aba425710a

Demographics
Sex at birth: female; Race: white.

Biospecimens (3 samples)
- Sample 0DV98N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV991: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV99N: Tissue type: Tumor; Specimen type: Solid Tissue.
